Somatic mutation profile of tumor specimen MP2PRT-PATKYM-TMP1-B (aliquot MP2PRT-PATKYM-TMP1-B-1-0-D-A817-36) from MP2PRT case MP2PRT-PATKYM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,716 days).
Specimen MP2PRT-PATKYM-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90b00f0b-977c-4a2e-b526-c6cc68d5a6af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKYM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKYM-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/478832d5-750e-4928-aa12-380418a8095f

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Nonsense Mutation 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1201768818, CM144469; called by muse, mutect2
- CSMD3 | c.3073G>C p.D1025H (on ENST00000297405 / NM_001363185.1; = p.D921H on NM_052900.3) | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV52277681, COSV52307119; called by muse, mutect2
- JRK | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 188/478 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as rs782360271, COSV101401200; called by muse, mutect2, varscan2
- P2RY4 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 189/256 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771836244; called by muse, mutect2, varscan2
- SLC9A4 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs201936592; called by muse, mutect2, varscan2
- SLITRK2 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 199/259 reads (77%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs373969433; called by muse, mutect2, varscan2
- TRIM49C | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 34/298 reads (11%) | catalogued as COSV71511012; called by muse, mutect2
- UBQLN3 | c.1638G>A p.M546I | Missense Mutation (SNP) | VAF 63/339 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1326958665, COSV61164722; called by muse, mutect2, varscan2
- APLF | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR52A5 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.955); called by muse, mutect2
- PITPNM1 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 120/431 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PNISR | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 35/229 reads (15%) | called by muse, mutect2, varscan2
- SNRPC | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- TMTC2 | c.2265C>G p.L755= | Splice Region (SNP) | VAF 18/376 reads (5%) | called by muse, mutect2
- ZFHX4 | c.10172C>T p.S3391L | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGO2 | c.114C>T p.I38= | Silent (SNP) | VAF 14/400 reads (4%) | called by muse, mutect2
- CMKLR1 | c.543C>A p.A181= (on ENST00000312143 / NM_001142344.2; = p.A179= on NM_004072.3) | Silent (SNP) | VAF 124/303 reads (41%) | called by muse, mutect2, varscan2
- CYP4B1 | c.1176C>A p.T392= | Silent (SNP) | VAF 157/438 reads (36%) | called by muse, mutect2
- MIB1 | c.234C>T p.I78= | Silent (SNP) | VAF 10/292 reads (3%) | catalogued as COSV55091580; called by muse, mutect2
- MUC16 | c.16290C>T p.S5430= | Silent (SNP) | VAF 71/482 reads (15%) | catalogued as rs780910635, COSV67455772; called by muse, mutect2, varscan2
- PCDHB3 | c.2130G>A p.A710= | Silent (SNP) | VAF 25/891 reads (3%) | catalogued as rs531712675, COSV50577138; called by muse, mutect2
- ZNF556 | c.741C>T p.R247= | Silent (SNP) | VAF 172/473 reads (36%) | catalogued as rs150733821; called by muse, mutect2, varscan2
- FBLN1 | c.1698-11430G>A | Intron (SNP) | VAF 84/489 reads (17%) | catalogued as rs1267166390; called by muse, mutect2, varscan2
